Somatic mutation profile of tumor specimen TARGET-30-PAVDBS-01A (aliquot TARGET-30-PAVDBS-01A-01D) from TARGET case TARGET-30-PAVDBS, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Peripheral nerves and autonomic nervous system of abdomen; Age at diagnosis: 3.3 years (1,212 days).
Specimen TARGET-30-PAVDBS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a984ac9d-9a32-4dce-9362-db88d7d9f2d2.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAVDBS-10A (Blood Derived Normal), aliquot TARGET-30-PAVDBS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21bb7aa6-b8b1-4e38-9cd5-2d0aac8a34da

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 16/57 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113994087, CM085230, COSV66555567, COSV66558183; ClinVar: pathogenic / likely pathogenic /  risk factor; called by muse, mutect2, varscan2
- EGFR | c.1924A>G p.K642E | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.028); catalogued as COSV51826171; called by muse, mutect2, varscan2
- MYH11 | c.4936C>A p.Q1646K | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
